Somatic mutation profile of tumor specimen MBCProject_1334_T1_WES (aliquot MBCProject_1334_T1_WES_1) from CMI case MBCProject_1334, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 61.4 years (22,433 days).
Specimen MBCProject_1334_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdc80874-839c-4e18-9498-f7f65d43ef49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1334_SALIVA (Saliva), aliquot MBCProject_1334_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11937a15-bbdb-4e5b-bbf3-75b5cb8f3c94

The open-access MAF lists 63 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 12, Intron 5, Frame Shift Del 3, Splice Region 2, 5'UTR 2, Nonsense Mutation 2, 5'Flank 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 36/103 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.403T>C p.C135R | Missense Mutation (SNP) | VAF 73/215 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519975, COSV52674321, COSV52706302, COSV52827707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.315); catalogued as rs1160627568, COSV55286815; called by muse, mutect2
- ADRA1D | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101063040; called by muse, mutect2
- ANO5 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.11); catalogued as COSV61087370; called by muse, mutect2
- CA1 | c.238C>T p.L80= | Splice Region (SNP) | VAF 80/1305 reads (6%) | catalogued as COSV56279528; called by muse, mutect2
- CCDC73 | c.2008A>G p.K670E | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV58799392; called by muse, mutect2, varscan2
- FOXP4 | c.1712del p.N571Mfs*22 (on ENST00000307972 / NM_001012426.1; = p.N558Mfs*22 on NM_138457.3) | Frame Shift Del (DEL) | VAF 20/184 reads (11%) | catalogued as COSV100332538; called by mutect2, pindel, varscan2
- GALT | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 56/455 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM065206, CM151305; called by muse, mutect2, varscan2
- GTF3C2 | c.814C>G p.P272A | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.115); catalogued as COSV53129220; called by muse, mutect2
- KRT6B | c.455T>C p.I152T | Missense Mutation (SNP) | VAF 27/574 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs756176376; called by muse, mutect2
- MAST4 | c.1469C>T p.P490L (on ENST00000403625 / NM_001164664.2; = p.P301L on NM_015183.3) | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764589271; called by muse, mutect2, varscan2
- PALD1 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs143276983; called by muse, mutect2, varscan2
- SERPINE2 | c.1076-4G>A | Splice Region (SNP) | VAF 49/212 reads (23%) | catalogued as rs567218200; called by muse, mutect2, varscan2
- SOX7 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs1222159969; called by muse, mutect2, varscan2
- ZNF548 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 13/338 reads (4%) | catalogued as COSV100278281; called by muse, mutect2
- ADCY8 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ADGRL3 | c.794C>A p.T265N (on ENST00000506720 / NM_001322402.2; = p.T197N on NM_015236.6) | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ANKRD53 | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 18/277 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.211); called by muse, mutect2
- CNOT1 | c.356T>A p.L119H | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DOCK2 | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 21/462 reads (5%) | SIFT tolerated (0.98); PolyPhen probably damaging (0.996); called by muse, mutect2
- ENO4 | c.1670G>A p.R557Q (on ENST00000622726; = p.R554Q on NM_001242699.2) | Missense Mutation (SNP) | VAF 13/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- EXOSC8 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 24/173 reads (14%) | called by muse, mutect2, varscan2
- GJA4 | c.326A>T p.K109M | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- HECTD4 | c.1631G>T p.G544V | Missense Mutation (SNP) | VAF 35/726 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); called by muse, mutect2
- LAMB1 | c.3268C>A p.H1090N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.113); called by muse, mutect2
- LAMB2 | c.3754G>T p.A1252S | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MGAM2 | c.4172G>T p.S1391I | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- MIA2 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RNF213 | c.2714G>T p.G905V | Missense Mutation (SNP) | VAF 23/532 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.258); called by muse, mutect2
- RPS6KA6 | c.1144C>T p.H382Y | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2
- RRAS | c.134T>A p.L45Q | Missense Mutation (SNP) | VAF 33/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SGO1 | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- SLK | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- SMC3 | c.3152G>C p.G1051A | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPDEF | c.883_896del p.K295Hfs*44 | Frame Shift Del (DEL) | VAF 25/110 reads (23%) | called by mutect2, pindel, varscan2
- THEGL | c.677del p.N226Tfs*28 | Frame Shift Del (DEL) | VAF 21/124 reads (17%) | called by mutect2, pindel, varscan2
- TKT | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TRAPPC5 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP35 | c.92A>T p.Q31L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF808 | c.951T>G p.C317W | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABHD16B | c.363C>T p.R121= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs1388141787; called by muse, mutect2, varscan2
- CCDC106 | c.777C>G p.L259= | Silent (SNP) | VAF 25/182 reads (14%) | called by muse, mutect2, varscan2
- CCL3 | c.249A>G p.K83= | Silent (SNP) | VAF 26/565 reads (5%) | called by muse, mutect2
- EIF2AK3 | c.2079A>T p.P693= | Silent (SNP) | VAF 18/516 reads (3%) | called by muse, mutect2
- FAM50A | c.666C>A p.T222= | Silent (SNP) | VAF 11/260 reads (4%) | catalogued as COSV50131116; called by muse, mutect2
- HAUS5 | c.1725G>A p.E575= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as COSV52548023; called by muse, mutect2, varscan2
- IGFALS | c.564G>A p.A188= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as rs746027443; called by muse, mutect2, varscan2
- KAT6A | c.1011T>G p.R337= | Silent (SNP) | VAF 9/189 reads (5%) | called by muse, mutect2
- RBBP9 | c.156G>A p.E52= | Silent (SNP) | VAF 19/504 reads (4%) | catalogued as COSV100464129; called by muse, mutect2
- SOD3 | c.279C>T p.L93= | Silent (SNP) | VAF 13/219 reads (6%) | called by muse, mutect2
- ZNF440 | c.346C>T p.L116= | Silent (SNP) | VAF 90/282 reads (32%) | called by muse, mutect2, varscan2
- ZNF692 | c.702C>G p.T234= | Silent (SNP) | VAF 223/434 reads (51%) | called by muse, mutect2, varscan2
- ANO4 | c.-108C>T | 5'UTR (SNP) | VAF 18/228 reads (8%) | catalogued as rs759282849, COSV100151364; called by muse, mutect2
- ANXA2 | c.-116-2743del | Intron (DEL) | VAF 20/189 reads (11%) | called by mutect2, pindel, varscan2
- AP000769.5 | chr11:65498989 T>G | 5'Flank (SNP) | VAF 27/528 reads (5%) | catalogued as rs754397792; called by muse, mutect2
- CFL2 | c.*2166A>G | 3'UTR (SNP) | VAF 48/107 reads (45%) | called by muse, mutect2, varscan2
- DENND4C | c.2881+784G>A | Intron (SNP) | VAF 11/126 reads (9%) | catalogued as rs754550117; called by muse, mutect2
- GPC1 | c.167-7769C>T | Intron (SNP) | VAF 25/126 reads (20%) | catalogued as rs1488214540; called by muse, mutect2, varscan2
- OFD1 | c.2758-30G>A | Intron (SNP) | VAF 33/180 reads (18%) | called by muse, mutect2, varscan2
- SUOX | c.-6G>C | 5'UTR (SNP) | VAF 40/507 reads (8%) | called by muse, mutect2
- U8 | chr15:32424704 A>C | 3'Flank (SNP) | VAF 8/162 reads (5%) | catalogued as rs754949201; called by muse, mutect2
- VPS13B | c.4820+15653G>A | Intron (SNP) | VAF 19/195 reads (10%) | called by muse, mutect2, varscan2
